Surgical pathology report (de-identified scan), TCGA case TCGA-H2-A26U, project TCGA-THCA (Thyroid Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-H2-A26U-01A (Primary Tumor).

[page 1 of 2]
Carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9 hr 4/27/11

DEPARTMENT OF PATHOLOGY AND LABORATORY MEDICINE

Date Coll:

SURGICAL PATHOLOGY REPORT

SPECIMEN

- A. Right lobe of thyroid
- B. Pretracheal lymph node
- C. Central cervical lymph node
- D. Left lobe thyroid

CLINICAL NOTES

PRE-OP DIAGNOSIS: Right thyroid nodule with atypical cells
CLINICAL HISTORY: Papillary carcinoma.

FROZEN SECTION DIAGNOSIS

- A) Thyroid, right lobe, excision - Papillary carcinoma
- B) Lymph nodes, pretracheal, excision - Negative for metastatic carcinoma (0/1).

GROSS DESCRIPTION

A. Received fresh for frozen section labeled "right lobe of thyroid" is a lobectomy specimen that measures 4.4 x 2.9 x 2 cm in dimension. Sections through the specimen show a white firm nodular lesion grossly suspicious for carcinoma that measures 1.5 cm in dimension. A representative section is submitted for frozen section and a touch preparation is made. The remaining thyroid shows degenerative and cystic changes. The tumor is entirely submitted for permanent section in cassettes A1 through A4 and the remaining thyroid is submitted for permanent section in cassettes A5 through A10. AS-10.

B. Received fresh for frozen section labeled "pretracheal lymph node" is a lymph node that measures .7 x .6 x .5 cm in dimension. The lymph node is entirely frozen.

C. Received fresh labeled "central cervical lymph node" are five soft tan pink-gold tissues ranging from 0.4-1.7 cm. in greatest dimension. The two largest tissues are bisected and the specimens are entirely submitted in three blocks as labeled.
BLOCK SUMMARY: 1 - Three whole tissues; 2-3 - one bisected tissue per cassette.

D. Received fresh labeled "left lobe thyroid" is a 13.2 gram, unoriented, 4.9 x 3.6 x 2.0 cm. soft portion of thyroid parenchyma. The capsule is delicate tan pink and no lymphoid or parathyroid tissues are identified. The specimen is inked entirely black and sectioned. The parenchyma is bosselated pale tan with focal areas of "normal appearing" red-brown beefy cut surfaces. No discrete mass lesion is identified grossly. The specimen is entirely submitted in a sequential manner in 10 blocks.

[page 2 of 2]
MICROSCOPIC DESCRIPTION

Histologic type: Papillary carcinoma

Primary tumor (pT): The tumor measures 1.5 cm in the right lobe and there are two microscopic foci in the left lobe that measure 3.5 mm and 1 mm in largest dimension.

The tumor shows minimal extrathyroidal extension in the right lobe, pT3.

Margins of resection: Positive in the right lobe.

Vascular invasion: Not identified.

Regional lymph nodes (pN): pN0

Distant metastasis (pM): pMx

Other findings: Marked chronic thyroiditis.

14x2, 4x3, 3x1

DIAGNOSIS

- A. Thyroid, right lobe, lobectomy -
Papillary carcinoma (see tumor characteristics in the microscopic description).
- B. Lymph node, pretracheal, excision -
One lymph node negative for metastatic carcinoma (0/1).
- C. Lymph nodes, central cervical, excision -
Six lymph nodes negative for metastatic carcinoma (0/6).
- D. Thyroid, left lobe, excision -
Two microscopic foci of organ-confined papillary carcinoma measuring 3.5 and 1 mm in dimension.

...D. (Electronic Signature)

--- End Of Report ---

Source: NCI Genomic Data Commons file 3933c076-47ed-402a-9bb7-555f5cfe11a8 (TCGA-H2-A26U.59095FF3-A312-44C5-956C-E0D6A6DBABBA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).